Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3385, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3385-01A (Primary Tumor).

[page 1 of 2]
[REDACTED] [REDACTED]

Result Name	Results	Units	Reference Range
☒ Surgical Pathology	COPY TO:		

COPY TO:

Pre-Op Diagnosis

Left renal mass

Post-Op Diagnosis

Same

Clinical History

Nothing dictated

Gross Description:

Received in a single container labeled [REDACTED] - left kidney" is a 730 gram left nephrectomy specimen previously partially covered by a moderate amount of perinephric adipose tissue and faced anteriorly by a minimal amount of Gerota's fascia. The specimen as received measures 20.7 x 12.6 x 7.5 cm. The margins of resection include 2.8 cm of grossly patent renal artery, 3.6 cm of grossly patent renal vein, and 9.3 cm of grossly patent ureter. The capsule strips with ease to reveal an organ measuring 14.2 x 7.1 x 5.8 cm. The cortex is slightly granular, lobulated, red brown. Noted on the posterior lateral aspect in the mid region of the specimen is a 4.0 x 3.6 x 1.3 cm gray tan partially sectioned plaque-like lesion. Sectioning this lesion reveals a nodular lesion measuring 3.5 x 3.0 x 3.0 cm. This has a thin intact gray white capsule and has a lobulated fleshy focally hemorrhagic focally hyalinized tan pink to yellow cut surface. This lesion slightly compresses the surrounding parenchyma and does not grossly appear to extend into it. The remaining renal parenchyma has a cortex measuring up to 0.9 cm which is slightly granular red brown. The cortical medullary junction is poorly defined. The medulla is red brown with sharp papillae. The calices and pelvis are lined by smooth gray white mucosa extending into the ureter. No additional gross lesions are identified. Within the surrounding adipose tissue there are no lesions or nodules. Also received in the same container are three tissue cassettes each labeled [REDACTED]. Representative sections are submitted labeled as follows: A - vascular and ureteral margins, B through F - representative lesion and surrounding tissue, G and H - representative grossly uninvolved parenchyma.

[REDACTED]
Microscopic Description:

The slides are reviewed labeled [REDACTED]

Final Diagnosis

Left kidney:

Tumor characteristics:

1. Histologic type: Renal cell carcinoma, clear cell type
2. Site: Neoplasm is identified on the posterior lateral aspect in the mid region of the kidney.
3. Size: 3.5 x 3.0 x 3.0 cm
4. Macroscopic extent of tumor: Neoplasm appears to be limited to the kidney.
- [REDACTED]

[page 2 of 2]
5. Nuclear grade: Fuhrman grade 2/4
6. Lymphovascular space invasion: Extensive perivascular neoplasm is identified but no intraluminal tumor is seen.
7. Transcapsular invasion: No
8. Renal vein invasion: No
9. Vena caval invasion: Not resected
10. Adrenal gland: Not identified

Surgical margin status:

1. Soft tissue margins: Negative
2. Ureteral margin: Negative
3. Vascular margins: Negative

Other significant findings:

1. Focal glomerulosclerosis.
2. Focal nephrocalcinosis.

Stage:

pT1a, Nx, Mx

CPT: 88307

Comments

Source: NCI Genomic Data Commons file c68fdeef-a116-4ed1-9c3b-edf62c94b85c (TCGA-A3-3385.3449CBD9-64B9-4BDC-BC6D-3E1E5294F40B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).